MMRF case MMRF_1816 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b959e7a7-8961-4e1f-b1c4-2cc227b907d6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.9 years (24,443 days); ISS stage: I; Days to last known disease status: 1,184 days (3.2 years); Days to last follow up: 1,184 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 96 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 100 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 133 days; Days to treatment end: 133 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 140 days; Days to treatment end: 140 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 232 days; Days to treatment end: 233 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 232 days; Days to treatment end: 562 days (1.5 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 232 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 239 days; Days to treatment end: 352 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 359 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 576 days (1.6 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,184.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 1): M Protein 2.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 88.3 mg/dL; Immunoglobulin G 37.6 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 6.25 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 8.9 g/dL; Glucose 5.94 mmol/L.
- Day 101 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.66 mg/dL; Hemoglobin 7.07 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 5.7 g/dL; Glucose 4.29 mmol/L.
- Day 178 (ECOG 1): M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.86 mg/dL; Immunoglobulin G 6.01 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 299 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 5.01 mmol/L.
- Day 255 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.015 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.618 mg/dL; Hemoglobin 6.45 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 5.5 g/dL; Glucose 4.68 mmol/L.
- Day 339 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.059 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.044 mg/dL; Hemoglobin 6.82 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 5.5 g/dL; Glucose 5.78 mmol/L.
- Day 457 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.061 mg/dL; Immunoglobulin G 1.75 g/L; Immunoglobulin A 0.077 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.38 mmol/L; Albumin 36 g/L; Total Protein 5.2 g/dL; Glucose 4.9 mmol/L.
- Day 548: Serum Free Immunoglobulin Light Chain, Kappa 0.426 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.624 mg/dL; Immunoglobulin G 1.2 g/L; Immunoglobulin A 0.152 g/L; Immunoglobulin M 0.101 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 5.8 g/dL; Glucose 4.68 mmol/L.
- Day 626 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.117 mg/dL; Immunoglobulin G 1.12 g/L; Immunoglobulin A 0.113 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 5.72 mmol/L.
- Day 709 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.109 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 0.923 g/L; Immunoglobulin A 0.101 g/L; Immunoglobulin M 0.105 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 5.6 g/dL; Glucose 5.45 mmol/L.
- Day 823 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.743 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.536 mg/dL; Immunoglobulin G 0.735 g/L; Immunoglobulin A 0.121 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 5.8 g/dL; Glucose 5.34 mmol/L.
- Day 913 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.143 mg/dL; Immunoglobulin G 0.522 g/L; Immunoglobulin A 0.082 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.24 mmol/L; Albumin 37 g/L; Total Protein 5.6 g/dL; Glucose 5.72 mmol/L.
- Day 969 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.071 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.143 mg/dL; Immunoglobulin G 0.553 g/L; Immunoglobulin A 0.226 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 2.9 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 45.1 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 5.45 mmol/L.
- Day 1,094 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 0.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.503 mg/dL; Immunoglobulin G 6.29 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 1.9 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 4.18 mmol/L.

Other clinical attributes
- Day -2: Weight: 50 kg; Height: 161 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1816_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_1816_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
